Gene-level copy-number profile of tumor specimen TCGA-36-2545-01A from TCGA case TCGA-36-2545, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 42.3 years (15,444 days).
Specimen TCGA-36-2545-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.1f85cffd-00d3-4063-90c5-ccf48b0bb014.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-2545-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c4a6cf63-1671-4d41-9ec7-14da7ff9a236

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 287; copy number 2: 14,301; copy number 3: 5,231; copy number 4: 28,559; copy number 5: 6,796; copy number 6: 2,910; copy number 7: 1,066; copy number 9: 526; copy number 10: 134.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-36-2545-01A-01D-1043-01): tumor purity 0.78, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 660 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:181,813,401–181,867,154, 4 genes, copy number 10: RN7SL703P, RNA5SP150, AC007547.2, AC007547.1.
- chr8:101,492,439–101,669,726, 1 gene, copy number 9 (within-gene range 7–9): GRHL2.
- chr8:101,686,542–145,066,685, 655 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 26. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
